Surgical pathology report (de-identified scan), TCGA case TCGA-60-2696, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2696-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 2R LYMPH NODE
B. 4R LYMPH NODE
C. LEFT UPPER LOBECTOMY
D. 11 L LYMPH NODE
E. 10 L LYMPH NODE
F. ANTERIOR SUPERIOR MEDIASTINAL MARGIN

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Left lung cancer.

INTRAOPERATIVE CONSULTATION:

FSA-FSB: No tumor seen. Diagnosis called [REDACTED]
FSC, Left upper lobe, bronchial margin: Negative for malignancy
FSF, Anterior/superior mediastinal margin: Negative for malignancy
Diagnoses called at [REDACTED] by [REDACTED]

GROSS DESCRIPTION:**A. 2R LYMPH NODE**

Received fresh for frozen section are two tan pink lymph nodes 0.6 x 0.3 x 0.2cm and 0.5 x 0.4 x 0.2cm. Toto FSA.

B. 4R LYMPH NODE

Received fresh for frozen section are two tan pink lymph nodes 0.2 x 0.2 x 0.2cm and 0.2 x 0.2 x 0.1cm. Toto FSB.

HW

C. LEFT UPPER LOBECTOMY

[page 2 of 3]
[REDACTED]

Received fresh labeled with the patient's identification and designated "left upper lobectomy" is a resected lobe of lung weighing 903 g and measuring 22 x 14.5 x 2.5 cm. The overlying visceral pleura is smooth and red. A palpable mass lies subjacent to the bronchial margin. Sectioning shows a firm beige centrally friable mass measuring 5.5 x 3.5 x 3 cm approaching the bronchial margin at distance of 0.2-cm, and 0.5-cm from the pleural surface. No additional lesions or nodules are grossly appreciated. The remainder of the specimen shows deep red consolidated lung parenchyma. A portion of the specimen is submitted for tissue procurement.

Representatively submitted:

FSC: Bronchial margin

C2: Additional bronchial margin

C3-C5: Possible peribronchial lymph nodes

C6-C7: Perpendicular sections, mass and bronchial margin

C8: Mass and overlying pleura

C9: Mass and normal appearing lung parenchyma

C10-C11: Uninvolved lung parenchyma

D. 11 L LYMPH NODE

Received in formalin labeled with the patient's identification and designated "11L lymph node" are two fragments of brown-tan soft tissue measuring 1.1 x 0.6 x 0.3 cm in aggregate. Entirely submitted, D1.

E. 10 L LYMPH NODE

Received in formalin labeled with the patient's identification and designated "10 L lymph node" is a fragment of brown-tan soft tissue measuring 0.4 x 0.2 x 0.2 cm. Entirely submitted, E1.

F. ANTERIOR/SUPERIOR MEDIASTINAL MARGIN

Received fresh labeled with the patient's identification and designated "anterior/superior mediastinal margin" are two pieces of tan-red soft tissue measuring 0.6 x 0.3 x 0.2 cm and 0.7 x 0.5 x 0.2 cm. Entirely submitted for frozen section, FSF.

[REDACTED]

DIAGNOSIS:

A. 2R LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

B. 4R LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

C. LEFT UPPER LOBE, LOBECTOMY:

- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, TUMOR SIZE 5.5 X 3.5 X 3.0 CM

- BRONCHIAL MARGIN, NEGATIVE FOR TUMOR

- TWO PERIBRONCHIAL LYMPH NODES, NEGATIVE FOR TUMOR (0/2)

- SEE TEMPLATE

D. 11L LYMPH NODE, EXCISION:

- TINY PIECE OF BLOOD CLOT, NO LYMPH NODE OR TUMOR IDENTIFIED

[page 3 of 3]
E. 10L LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

F. ANTERIOR SUPERIOR MEDIASTINAL MARGIN, EXCISION:

- BENIGN LUNG PARENCHYMA AND FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR

SYNOPTIC REPORT - LUNG

Surgical Procedure: Lobectomy

Laterality: Left

Tumor Site: Upper lobe

Tumor Location: Central

Tumor Size: Greatest diameter: 5.5cm

Additional dimensions: 3.5cm x 3cm

WHO CLASSIFICATION

Squamous cell carcinoma

Conventional type 8070/3

Histologic Grade: G2: Moderately differentiated

Angiolymphatic Invasion: Absent

Bronchial Margins: Bronchial margins uninvolved

Visceral Pleural Involvement: Absent

Satellite Tumor(s): Absent

Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Negative 0 / 3

N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
N/A

N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular
Negative 0 / 2

Non-Neoplastic Lung: Emphysematous changes
Hemorrhage

Additional Pathologic Findings: None identified

Pathological Staging (pTNM): pT 2 N 0 M X

Source: NCI Genomic Data Commons file 419b4d9e-1748-4565-8de6-7a5734ca8f23 (TCGA-60-2696.AFE56CAB-1FD2-4503-899B-CBFEB79EE7A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).